MMRF case MMRF_1890 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a4c12827-4070-4964-b2e0-ccea378e1d0a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Dead; Days to death: 134 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.8 years (17,444 days); ISS stage: II; Days to last known disease status: 134 days; Days to last follow up: 134 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 119 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 121 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 129 days; Days to treatment end: 133 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 134.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 2.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1240 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21 mg/dL; Immunoglobulin G 1.97 g/L; Immunoglobulin A 37.9 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 5.75 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.2 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.8 mmol/L; Albumin 31 g/L; Total Protein 8.8 g/dL; Glucose 6.6 mmol/L.
- Day 76: M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.007 mg/dL; Immunoglobulin G 1.14 g/L; Immunoglobulin A 9.2 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L.
- Day 105: Lactate Dehydrogenase 14.4 µkat/L; Hemoglobin 4.28 mmol/L; Platelets 51 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 20.3 mmol/L; Calcium 2.08 mmol/L; Albumin 19 g/L; Total Protein 3.9 g/dL; Glucose 7.37 mmol/L.

Other clinical attributes
- Day -13: Weight: 73 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1890_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1890_2_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
